Somatic mutation profile of tumor specimen TCGA-61-2102-01A (aliquot TCGA-61-2102-01A-01W-0722-08) from TCGA case TCGA-61-2102, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.6 years (27,256 days).
Specimen TCGA-61-2102-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ab3ebdd-4ccb-469a-b3f1-8496f04c193e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2102-11A (Solid Tissue Normal), aliquot TCGA-61-2102-11A-01W-0723-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2be17ad-5b31-4dc9-8329-a8019f6f95a0

The open-access MAF lists 69 somatic variants for this specimen: 54 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 49, Silent 15, Frame Shift Ins 1, Frame Shift Del 1, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC5A5 | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909180, CM991141; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 9/9 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2
- ADGRF1 | c.643G>C p.V215L | Missense Mutation (SNP) | VAF 83/402 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as rs1319066384, COSV51944370; called by muse, varscan2
- ASPM | c.6387G>A p.M2129I | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV99659565; called by muse, mutect2, varscan2
- ATP10D | c.911A>C p.N304T | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56704962, COSV99905888; called by muse, mutect2, varscan2
- ATP9B | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as COSV56946507, COSV56947551; called by muse, mutect2, varscan2
- B3GALT2 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.148); catalogued as COSV104427328, COSV66463885; called by muse, mutect2, varscan2
- BEST4 | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.273); catalogued as COSV64733664; called by muse, mutect2, varscan2
- CA10 | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.718); catalogued as COSV53341371; called by muse, mutect2, varscan2
- CD101 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV56716691; called by muse, mutect2, varscan2
- CDKN2C | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52954267, COSV52955470; called by muse, mutect2, varscan2
- CELA2A | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as COSV62747270; called by muse, mutect2, varscan2
- CIT | c.5719G>A p.G1907S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs367930288; called by muse, mutect2, varscan2
- CTSK | c.409G>C p.G137R | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99648540; called by muse, mutect2, varscan2
- DCC | c.1345T>A p.W449R | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100498253; called by muse, varscan2
- DCSTAMP | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV52576679; called by muse, mutect2, varscan2
- DDX39B | c.1246G>C p.D416H | Missense Mutation (SNP) | VAF 56/195 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV66018744; called by muse, mutect2, varscan2
- FBN2 | c.2075T>A p.M692K | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as rs146586596; called by muse, mutect2, varscan2
- FRYL | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51962239; called by muse, mutect2
- GLI2 | c.973G>T p.A325S | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.96); PolyPhen benign (0.08); catalogued as COSV58036597; called by muse, mutect2, varscan2
- HMCN1 | c.7598G>A p.R2533H | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs199987140, COSV54884013; called by muse, mutect2, varscan2
- INVS | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 182/298 reads (61%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as rs759684253, COSV99317110; called by muse, mutect2, varscan2
- IQGAP2 | c.4397G>C p.G1466A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV57169530; called by muse, mutect2, varscan2
- KCTD18 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV63344017, COSV63344257, COSV63344277; called by muse, mutect2, varscan2
- LRBA | c.6911A>C p.H2304P | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63951267; called by muse, mutect2, varscan2
- MAST3 | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV53218235; called by muse, mutect2
- MCOLN2 | c.1397T>C p.F466S | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV52293856; called by muse, mutect2, varscan2
- MDM1 | c.2000A>T p.Q667L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV57444896; called by muse, mutect2, varscan2
- MON2 | c.3169A>T p.T1057S | Missense Mutation (SNP) | VAF 178/659 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.025); catalogued as COSV99741645; called by muse, varscan2
- MUC17 | c.3794G>T p.G1265V | Missense Mutation (SNP) | VAF 117/439 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.972); catalogued as rs776393672, COSV60282394; called by muse, mutect2, varscan2
- NDUFA7 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV100035419; called by muse, mutect2, varscan2
- NEXN | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53942129; called by muse, mutect2, varscan2
- NPLOC4 | c.239C>G p.S80W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1157166475, COSV58615121; called by muse, mutect2, varscan2
- PASK | c.3482C>A p.T1161N | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV52149951; called by muse, mutect2, varscan2
- POF1B | c.668C>G p.S223C | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV99426000; called by muse, mutect2
- PPL | c.3198_3203del p.A1068_E1069del | In Frame Del (DEL) | VAF 83/91 reads (91%) | catalogued as COSV52166405; called by mutect2, pindel, varscan2
- PRKDC | c.3397C>G p.H1133D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58046309; called by muse, mutect2, varscan2
- PTPRB | c.2669C>A p.T890K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54243493, COSV99715878; called by muse, mutect2, varscan2
- RNASE9 | c.379A>C p.I127L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV58880111; called by mutect2, varscan2
- SP100 | c.2356G>C p.V786L | Missense Mutation (SNP) | VAF 113/212 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as COSV60842390; called by muse, mutect2, varscan2
- SPN | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as rs1392004633, COSV64070062; called by muse, mutect2, varscan2
- SPTAN1 | c.3469C>G p.L1157V | Missense Mutation (SNP) | VAF 60/60 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63985832; called by muse, mutect2, varscan2
- SRRM2 | c.2818A>G p.R940G | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs747745870, COSV57069670; called by muse, mutect2, varscan2
- SYNE2 | c.12841G>C p.A4281P | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.691); catalogued as COSV100646685; called by muse, mutect2, varscan2
- TBC1D4 | c.2980C>G p.L994V | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV66488056; called by muse, mutect2, varscan2
- TPM2 | c.190G>C p.V64L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV61405123, COSV61406525; called by muse, mutect2, varscan2
- TRAPPC8 | c.3956C>T p.S1319L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as COSV51968239; called by muse, mutect2, varscan2
- ZNF383 | c.198G>A p.M66I | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV61938692; called by muse, mutect2, varscan2
- ZNF44 | c.1720C>A p.H574N (on ENST00000356109 / NM_001164276.2; = p.H526N on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633474; called by muse, mutect2
- ZNF761 | c.599C>A p.S200* | Nonsense Mutation (SNP) | VAF 65/117 reads (56%) | catalogued as COSV61887792; called by muse, mutect2, varscan2
- ZSCAN4 | c.398T>G p.V133G | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56591723; called by muse, mutect2, varscan2
- C16orf70 | c.231+2dup p.X77_splice | Splice Site (INS) | VAF 22/40 reads (55%) | called by mutect2, pindel, varscan2
- CHRNA6 | c.336dup p.D113Rfs*2 | Frame Shift Ins (INS) | VAF 56/212 reads (26%) | called by mutect2, pindel, varscan2
- PIP4K2A | c.399_402del p.F134Tfs*25 | Frame Shift Del (DEL) | VAF 11/93 reads (12%) | called by mutect2, pindel
- CACNA1C | c.4407C>T p.N1469= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as COSV59702520; called by muse, mutect2, varscan2
- CCDC126 | c.408G>A p.S136= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs368070236, COSV100278136; called by muse, mutect2
- CDCA7L | c.264G>T p.T88= | Silent (SNP) | VAF 16/244 reads (7%) | catalogued as COSV100650956, COSV62259805; called by muse, mutect2
- ERGIC2 | c.397A>C p.R133= | Silent (SNP) | VAF 32/36 reads (89%) | catalogued as COSV64111516; called by muse, mutect2, varscan2
- FAT4 | c.4026C>T p.S1342= | Silent (SNP) | VAF 115/217 reads (53%) | catalogued as rs766699706, COSV67882513, COSV67883668; called by muse, mutect2, varscan2
- GRIK3 | c.393C>T p.P131= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV100902420, COSV66136621; called by muse, mutect2, varscan2
- HCAR3 | c.18G>A p.L6= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs762656705, COSV63671632; called by muse, mutect2
- HOXD10 | c.252G>A p.P84= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV50898980; called by muse, mutect2
- LRRC39 | c.195G>A p.L65= | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as COSV61582772; called by muse, mutect2, varscan2
- MGMT | c.321C>T p.I107= (on ENST00000306010; = p.I76= on NM_002412.5) | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs112373357; called by muse, mutect2, varscan2
- MTCL1 | c.4011G>A p.S1337= (on ENST00000306329 / NM_001378206.1; = p.S1018= on NM_015210.4) | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs1168242195, COSV60404135; called by muse, mutect2, varscan2
- NDUFA7 | c.150C>T p.S50= | Silent (SNP) | VAF 39/46 reads (85%) | catalogued as COSV100035417; called by muse, mutect2, varscan2
- PCDHB4 | c.1776C>T p.D592= | Silent (SNP) | VAF 51/77 reads (66%) | catalogued as COSV52028277; called by muse, mutect2, varscan2
- RPS8 | c.360C>T p.P120= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1031658374, COSV63234337; called by muse, mutect2, varscan2
- RSL24D1 | c.390C>T p.N130= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV53065266; called by muse, mutect2, varscan2
